Surgical pathology report (de-identified scan), TCGA case TCGA-55-7815, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-7815-01A (Primary Tumor).

[page 1 of 3]
NAME:

DOB:

SEX:

AGE:

ROOM #:

MR#:

PT CLASS:

CLINIC CODE:

ADMIT DATE:

DISCH DATE:

ACCT#:

ATTENDING PHYSICIAN:

ADMITTING PHYSICIAN:

SURGERY CASE #:

SURGERY CASE #: FINAL

DATE OF SURGERY:

SURGEON:

SPECIMEN:

- A. Right lower and middle lobe, lung
- B. Right interlobar node
- C. Right hilar
- D. Lower paratracheal right

SECTION DX:

Vascular and bronchial margins are benign. Parenchymal margin is 2.5 cm from the tumor grossly.

OPERATIVE PROCEDURE:

Thoracotomy with lobectomy

PREOPERATIVE DIAGNOSIS:

Right lung mass

POSTOPERATIVE DIAGNOSIS:

Right lung mass

*****DIAGNOSIS*****

- A. Right lower and middle lobe, lobectomy:
Well-differentiated adenocarcinoma, 6.0 cm in greatest dimension.
Adenocarcinoma focally involves pleural surface.
Lymphovascular invasion or perineural invasion not identified.
Bronchial and vascular resection margins negative for malignancy.
Six peribronchial/hilar lymph nodes, negative for metastatic malignancy (0/6).
Non-neoplastic lung with congestion and mild chronic inflammation.
- B. Right interlobe node:
Three lymph nodes, negative for metastatic malignancy (0/3):
- C. Right hilar lymph node:
One lymph node, negative for metastatic malignancy (0/1).
- D. Lower paratracheal right lymph node:
Three lymph nodes, negative for metastatic malignancy (0/3).

Pathologic staging: pT2a, pNO, pMX.

[page 2 of 3]
MICROSCOPIC EXAMINATION:

A,B,C,D: A microscopic examination was performed to render the above diagnosis. [REDACTED]

GROSS:

- A. Specimen received fresh for frozen section diagnosis labeled "right lower and middle lobe" and consists of right lower and middle lobe weighing 234 grams and measuring 18 x 16 x 4.5 cm. The bronchial remnant measures 1.5 cm in length and 2.0 cm in diameter. The bronchial and vascular margins are submitted for frozen section diagnosis labeled FS1. Adjacent to the bronchial resection margin is a 6 cm in length pleural area closed by a staple line. The bronchial tree is traced and no endobronchial lesions are noted. Located 2.8 cm from the bronchial resection margin is a 6 x 4 cm gray, solid, circumscribed tumor mass. The pleura at the level of tumor mass reveals a gray, puckered surface and it's marked with blue ink. Grossly the tumor extends up to the inked pleural surface. The tumor mass is located 2.5 cm from the stapled resection margin. Sectioning through the rest of the lung parenchyma reveals a brown-tan, slightly congested surface. No additional lesions are noted. Multiple peribronchial lymph nodes are identified. RS10.

Cassettes:

1. Frozen section bronchial resection margin.
- 2-5. Tumor mass with blue inked pleural surface.
- 6-7. Tumor mass with bronchial tree.
8. Tumor mass with adjacent lung tissue.
9. Lung tissue closer to the stapled area.
10. Hilar lymph nodes.
- B. Labeled "right interlobar node" is a cluster of lymph nodes measuring 0.8 x 0.5 x 0.5 cm. TS1. [REDACTED]
- C. Labeled "right hilar" is a gray-black anthracotic lymph node measuring 1 x 0.6 x 0.5 cm. Bisected TS1.
- D. Labeled "lower paratracheal right" are three gray-brown possible lymph node like structure tissue which are covered by fibrofatty tissue measuring 2 x 1.5 x 0.5 cm. TS1. [REDACTED]

[page 3 of 3]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 26af3981-7bfc-4adc-9290-69a280cef463 (TCGA-55-7815.4CABA554-2BB8-4158-AF8A-9690D4D5F73C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).